Somatic mutation profile of tumor specimen TCGA-AP-A0LN-01A (aliquot TCGA-AP-A0LN-01A-11W-A062-09) from TCGA case TCGA-AP-A0LN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 56.7 years (20,704 days).
Specimen TCGA-AP-A0LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63ceba64-3d89-4db4-8fdd-0f1aab715df7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LN-10A (Blood Derived Normal), aliquot TCGA-AP-A0LN-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/909e980c-249b-4ed5-916b-28edc6ee3498

The open-access MAF lists 62 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 42, Silent 10, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 30/79 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 41/107 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG1 | c.1152G>C p.L384F | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV59207903; called by muse, mutect2, varscan2
- AMY1C | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 199/681 reads (29%) | catalogued as rs752371105, COSV64406893; called by muse, mutect2, varscan2
- ANK3 | c.5417C>A p.S1806* | Nonsense Mutation (SNP) | VAF 258/482 reads (54%) | catalogued as COSV55070672; called by muse, mutect2, varscan2
- ARHGEF9 | c.1005C>A p.N335K | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV53637032; called by muse, mutect2, varscan2
- ASXL3 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52473245, COSV99323657; called by muse, mutect2, varscan2
- ATP2B4 | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 203/493 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58181232; called by muse, mutect2, varscan2
- ATRN | c.1549C>G p.H517D | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53531171; called by muse, mutect2, varscan2
- BRD3 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV57705251; called by muse, mutect2, varscan2
- CHD4 | c.5327A>G p.K1776R (on ENST00000357008 / NM_001363606.2; = p.K1787R on NM_001273.5) | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58906689; called by muse, mutect2, varscan2
- CNTNAP5 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV70498915; called by muse, mutect2, varscan2
- DACT1 | c.1704G>T p.R568S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV60022371; called by muse, mutect2, varscan2
- DCAF8L1 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as rs760109139, COSV71595414; called by muse, mutect2, varscan2
- EIF3CL | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 197/638 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV101086011; called by muse, mutect2, varscan2
- EXD2 | c.1748G>A p.R583H (on ENST00000312994 / NM_001193362.1; = p.R458H on NM_018199.3) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339900802, COSV57280934; called by muse, mutect2
- GABPB2 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs756909765, COSV64461205; called by muse, mutect2, varscan2
- GLUD2 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV60152581; called by muse, mutect2, varscan2
- HTATSF1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV54478644; called by muse, mutect2, varscan2
- IL22RA2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV51664094; called by muse, mutect2, varscan2
- LAMC1 | c.4652T>C p.V1551A | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51156703; called by muse, mutect2, varscan2
- LIMD1 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56268926, COSV56269275, COSV56270877; called by muse, mutect2, varscan2
- LPAR4 | c.1010A>G p.E337G | Missense Mutation (SNP) | VAF 160/464 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as COSV70913069; called by muse, mutect2, varscan2
- MCM10 | c.1066G>A p.A356T (on ENST00000484800 / NM_182751.3; = p.A355T on NM_018518.5) | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV66335711; called by muse, mutect2
- MYH15 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV56315366; called by muse, mutect2, varscan2
- OR1F1 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV58961838; called by muse, mutect2, varscan2
- OR5F1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs534436960, COSV53546798; called by muse, mutect2
- PALLD | c.1891A>C p.K631Q | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.08); catalogued as COSV54987921; called by muse, mutect2, varscan2
- PCDHB7 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.627); catalogued as rs558696629, COSV50794466; called by muse, mutect2, varscan2
- PGM3 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 28/218 reads (13%) | catalogued as rs142161221, COSV52285147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM10 | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV58803336; called by muse, mutect2
- PTEN | c.11_14del p.I4Tfs*19 | Frame Shift Del (DEL) | VAF 97/182 reads (53%) | catalogued as COSV64301496; called by mutect2, pindel, varscan2
- PTPRD | c.5473G>C p.G1825R | Missense Mutation (SNP) | VAF 101/320 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61925985, COSV61930823, COSV61976104; called by muse, mutect2, varscan2
- RALGAPA2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV52504455; called by muse, mutect2, varscan2
- RYR3 | c.8338C>T p.R2780W (on ENST00000389232; = p.R2781W on NM_001036.6) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772102927, COSV66801402; called by muse, mutect2, varscan2
- SETDB1 | c.3695T>G p.V1232G | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54988596; called by muse, mutect2, varscan2
- SEZ6L | c.2028C>A p.S676R | Missense Mutation (SNP) | VAF 201/497 reads (40%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.954); catalogued as COSV50672222; called by muse, mutect2, varscan2
- SGIP1 | c.2257T>A p.L753M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV52774330, COSV99392462; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 147/420 reads (35%) | PolyPhen probably damaging (0.996); catalogued as COSV60341456; called by muse, mutect2, varscan2
- TRPV2 | c.1428C>G p.F476L | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV58429390; called by muse, mutect2, varscan2
- USP19 | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490168078, COSV60047334; called by muse, mutect2, varscan2
- WDR59 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1263684635, COSV50939489; called by muse, mutect2, varscan2
- ZBTB4 | c.2501G>A p.G834E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs959001515, COSV60141369; called by muse, mutect2, varscan2
- ZNF292 | c.3786C>A p.F1262L | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.97); catalogued as COSV60543326; called by muse, mutect2, varscan2
- ZNF300 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 25/536 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs771864193, COSV51032314; called by muse, mutect2
- ZNF366 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs778659389, COSV59217470; called by muse, mutect2, varscan2
- CIAO2A | c.72_96del p.G25Wfs*6 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- IARS2 | c.1233del p.M412Wfs*4 | Frame Shift Del (DEL) | VAF 94/282 reads (33%) | called by mutect2, pindel, varscan2
- NIPBL | c.5329-15_5334del p.X1777_splice | Splice Site (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- NYNRIN | c.448del p.T150Pfs*10 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- PCDHB5 | c.1067del p.P356Qfs*8 | Frame Shift Del (DEL) | VAF 127/395 reads (32%) | called by mutect2, pindel, varscan2
- PTEN | c.374_400del p.K125_V133del | In Frame Del (DEL) | VAF 102/618 reads (17%) | called by mutect2, pindel
- CDC37 | c.732C>T p.A244= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs955251838, COSV55769206; called by muse, mutect2, varscan2
- DMP1 | c.873C>T p.V291= | Silent (SNP) | VAF 88/219 reads (40%) | catalogued as COSV56819905, COSV56821433; called by muse, mutect2, varscan2
- DSCAM | c.678C>G p.S226= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV68031896; called by muse, mutect2, varscan2
- LCT | c.4428C>T p.L1476= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs1274873963, COSV51553955; called by muse, mutect2, varscan2
- NPR3 | c.1215C>T p.S405= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as rs1191815267, COSV54090797, COSV99423827; called by muse, mutect2, varscan2
- OR5I1 | c.447G>A p.L149= | Silent (SNP) | VAF 88/252 reads (35%) | catalogued as rs781015372, COSV56888246; called by muse, mutect2, varscan2
- PRKRA | c.570C>G p.A190= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as COSV57869774; called by muse, mutect2, varscan2
- QRFP | c.225G>A p.Q75= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV58065054; called by muse, mutect2, varscan2
- RAPGEF1 | c.2151G>A p.E717= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV64700988; called by muse, mutect2, varscan2
- USP51 | c.33C>T p.S11= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV72351822; called by muse, mutect2, varscan2
